Somatic mutation profile of tumor specimen TCGA-06-0881-01A (aliquot TCGA-06-0881-01A-02W-0424-08) from TCGA case TCGA-06-0881, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 50.0 years (18,278 days).
Specimen TCGA-06-0881-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f0ca7cc8-bccf-4414-9426-a7eb9d6d4dbf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0881-10A (Blood Derived Normal), aliquot TCGA-06-0881-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5d28348-c7cc-4e1c-a7bf-962c328d3d77

The open-access MAF lists 122 somatic variants for this specimen: 88 protein-altering or splice-affecting, 31 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 31, Frame Shift Ins 29, Nonsense Mutation 3, Splice Region 1, Intron 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 292/2290 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs149840192, COSV51765841, COSV51768139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- LRP2 | c.13139dup p.C4381Mfs*12 | Frame Shift Ins (INS) | VAF 42/272 reads (15%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- NEUROD1 | c.616dup p.H206Pfs*38 | Frame Shift Ins (INS) | VAF 18/100 reads (18%) | catalogued as rs387906384; ClinVar: pathogenic; called by mutect2, varscan2
- PIGO | c.2361dup p.T788Hfs*5 | Frame Shift Ins (INS) | VAF 15/122 reads (12%) | catalogued as rs770591449; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PTEN | c.314G>A p.C105Y | Missense Mutation (SNP) | VAF 82/915 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782343, CM991080, COSV64290665, COSV64299259, COSV64307337; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2
- ABCA4 | c.4251C>T p.F1417= | Splice Region (SNP) | VAF 14/120 reads (12%) | catalogued as CD132928; called by muse, mutect2, varscan2
- ADAM23 | c.2340dup p.K781Qfs*3 | Frame Shift Ins (INS) | VAF 16/81 reads (20%) | catalogued as rs767549806; called by mutect2, varscan2
- ADGRB3 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 64/732 reads (9%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.931); catalogued as COSV65427670; called by mutect2, varscan2
- AHNAK | c.11853A>T p.E3951D | Missense Mutation (SNP) | VAF 38/838 reads (5%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as rs1166145824; called by muse, mutect2
- ALDH1A3 | c.849dup p.K284Efs*11 | Frame Shift Ins (INS) | VAF 16/142 reads (11%) | catalogued as rs758955164; called by mutect2, varscan2
- ANG | c.265C>T p.H89Y | Missense Mutation (SNP) | VAF 32/884 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100390827, COSV59012489; called by muse, mutect2
- AOX1 | c.521A>G p.K174R | Missense Mutation (SNP) | VAF 114/1294 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV65983245; called by mutect2, varscan2
- ARFGEF1 | c.4655dup p.P1553Tfs*7 | Frame Shift Ins (INS) | VAF 15/132 reads (11%) | catalogued as rs774148781; called by mutect2, varscan2
- ARHGEF7 | c.1261G>A p.E421K (on ENST00000375741 / NM_001113511.2; = p.E243K on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs772627389; called by muse, varscan2
- ATXN7 | c.2340dup p.T781Hfs*6 | Frame Shift Ins (INS) | VAF 12/70 reads (17%) | catalogued as rs779764089; called by mutect2, varscan2
- BAG6 | c.1169dup p.T391Nfs*29 | Frame Shift Ins (INS) | VAF 16/64 reads (25%) | catalogued as rs745882580; called by mutect2, varscan2
- BEST3 | c.1332dup p.R445Qfs*58 | Frame Shift Ins (INS) | VAF 14/114 reads (12%) | catalogued as rs779566914; called by mutect2, varscan2
- CDH18 | c.1454C>T p.P485L | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.206); catalogued as COSV99937407; called by muse, mutect2, varscan2
- CDH18 | c.1453C>G p.P485A | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs750128928, COSV56972721; called by muse, mutect2, varscan2
- CDYL | c.1493C>T p.S498F (on ENST00000328908 / NM_001368125.1; = p.S444F on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.988); catalogued as COSV59360240; called by muse, varscan2
- COL5A1 | c.4706dup p.E1571Rfs*53 | Frame Shift Ins (INS) | VAF 8/82 reads (10%) | catalogued as rs764778680; called by mutect2, pindel
- DHFR | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 49/986 reads (5%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.891); catalogued as rs1000980239; called by muse, mutect2
- EPHA1 | c.2807C>T p.S936L | Missense Mutation (SNP) | VAF 377/1167 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as rs765474060, COSV51972385; called by muse, mutect2, varscan2
- EPHX1 | c.400dup p.Q134Pfs*26 | Frame Shift Ins (INS) | VAF 34/300 reads (11%) | catalogued as rs756407271; called by mutect2, varscan2
- ESPL1 | c.5897G>A p.R1966Q | Missense Mutation (SNP) | VAF 56/450 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs970139194; called by muse, varscan2
- FAM219A | c.492dup p.K165Qfs*39 (on ENST00000445726; = p.K148Qfs*39 on NM_147202.2 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 14/106 reads (13%) | catalogued as rs760074479; called by mutect2, varscan2
- FER1L6 | c.5185G>A p.D1729N | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.11); catalogued as COSV101205869; called by muse, mutect2, varscan2
- FGA | c.1766A>G p.Y589C | Missense Mutation (SNP) | VAF 38/205 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.408); catalogued as COSV57399340; called by muse, mutect2, varscan2
- FLG | c.6140G>A p.S2047N | Missense Mutation (SNP) | VAF 41/549 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as rs758506209, COSV64239115; called by muse, mutect2
- FRMD4A | c.3014dup p.S1006Kfs*25 | Frame Shift Ins (INS) | VAF 26/153 reads (17%) | catalogued as rs752538869; called by mutect2, varscan2
- GCNT2 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 386/1420 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65457859; called by mutect2, varscan2
- GNAZ | c.612dup p.Q205Afs*35 | Frame Shift Ins (INS) | VAF 32/257 reads (12%) | catalogued as rs752075537; called by mutect2, varscan2
- HUWE1 | c.8131G>A p.D2711N | Missense Mutation (SNP) | VAF 235/1327 reads (18%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.015); catalogued as COSV53358213; called by muse, mutect2, varscan2
- IRS4 | c.1772dup p.K592Qfs*12 | Frame Shift Ins (INS) | VAF 28/160 reads (18%) | catalogued as rs780982673; called by mutect2, varscan2
- ITSN1 | c.472dup p.L158Pfs*3 | Frame Shift Ins (INS) | VAF 11/100 reads (11%) | catalogued as rs751926247; called by mutect2, varscan2
- LRP1 | c.12575dup p.D4193Rfs*9 | Frame Shift Ins (INS) | VAF 38/248 reads (15%) | catalogued as rs757410385; called by mutect2, varscan2
- MPP3 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1364577150; called by muse, mutect2
- MYH3 | c.4427G>A p.R1476H | Missense Mutation (SNP) | VAF 24/458 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.421); catalogued as rs757688078, COSV56868642; called by muse, mutect2
- NOD2 | c.1583dup p.D529Rfs*50 | Frame Shift Ins (INS) | VAF 16/138 reads (12%) | catalogued as rs754073471; ClinVar: uncertain significance; called by mutect2, varscan2
- NOL9 | c.478C>A p.Q160K | Missense Mutation (SNP) | VAF 114/2186 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60228047; called by muse, mutect2
- NRXN2 | c.808dup p.A270Gfs*27 | Frame Shift Ins (INS) | VAF 63/277 reads (23%) | catalogued as rs754860965; called by mutect2, varscan2
- PIK3C2B | c.859dup p.R287Pfs*38 | Frame Shift Ins (INS) | VAF 70/560 reads (13%) | catalogued as rs749506841; called by mutect2, varscan2
- PPRC1 | c.2819dup p.P941Tfs*75 | Frame Shift Ins (INS) | VAF 44/266 reads (17%) | catalogued as rs768056539; called by mutect2, varscan2
- PRCC | c.1138dup p.Q380Pfs*12 | Frame Shift Ins (INS) | VAF 50/312 reads (16%) | catalogued as rs778683789; called by mutect2, varscan2
- RALGAPB | c.1142dup p.H382Tfs*2 | Frame Shift Ins (INS) | VAF 21/144 reads (15%) | catalogued as rs756557178; called by mutect2, varscan2
- RYR2 | c.8145G>T p.E2715D | Missense Mutation (SNP) | VAF 77/165 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.904); catalogued as rs200420897; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SEC61A2 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 398/1441 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs1479543999, COSV100036292; called by muse, mutect2, varscan2
- SERPINA3 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 70/678 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.399); catalogued as COSV67587161; called by muse, mutect2
- SLC6A18 | c.634A>C p.T212P | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777600288; called by muse, mutect2
- SLC7A10 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1429134939; called by muse, mutect2, varscan2
- SPTBN2 | c.6422G>A p.G2141E | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.184); catalogued as COSV59452203; called by muse, mutect2
- SYT7 | c.1085G>A p.S362N | Missense Mutation (SNP) | VAF 28/446 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.724); catalogued as COSV55659103; called by muse, mutect2
- TEAD2 | c.883dup p.H295Pfs*19 | Frame Shift Ins (INS) | VAF 55/393 reads (14%) | catalogued as rs763321097; called by mutect2, varscan2
- TFE3 | c.1445dup p.P483Tfs*138 | Frame Shift Ins (INS) | VAF 32/150 reads (21%) | catalogued as rs782753958; called by mutect2, varscan2
- THBS2 | c.2035G>A p.E679K | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.964); catalogued as rs1474976569; called by muse, mutect2, varscan2
- TSC2 | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 18/273 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201144475; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- TSKS | c.1748dup p.Q585Tfs*7 | Frame Shift Ins (INS) | VAF 30/248 reads (12%) | catalogued as rs749002253; called by mutect2, varscan2
- TSPEAR | c.199dup p.R67Pfs*15 | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | catalogued as rs782155959; called by pindel, varscan2
- TTN | c.96185G>A p.R32062Q (on ENST00000591111; = p.R24638Q on NM_003319.4) | Missense Mutation (SNP) | VAF 42/1098 reads (4%) | PolyPhen probably damaging (0.992); catalogued as rs576025689, COSV59878997; called by muse, mutect2
- TTN | c.67295C>G p.T22432R (on ENST00000591111; = p.T15008R on NM_003319.4) | Missense Mutation (SNP) | VAF 22/382 reads (6%) | PolyPhen possibly damaging (0.448); catalogued as rs753519331, COSV60256517; called by muse, mutect2
- TTN | c.2996G>A p.R999H (on ENST00000591111; = p.R953H on NM_003319.4) | Missense Mutation (SNP) | VAF 24/442 reads (5%) | PolyPhen probably damaging (0.95); catalogued as rs371757623; ClinVar: uncertain significance; called by muse, mutect2
- USP13 | c.1896dup p.I633Hfs*5 | Frame Shift Ins (INS) | VAF 11/88 reads (13%) | catalogued as rs780272979; called by mutect2, varscan2
- ZNF425 | c.1222C>T p.H408Y | Missense Mutation (SNP) | VAF 84/920 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65200917; called by muse, mutect2
- ZNF551 | c.1700C>T p.S567F | Missense Mutation (SNP) | VAF 21/584 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.045); catalogued as COSV56594625; called by muse, mutect2
- CTNNAL1 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 36/994 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2
- ENOPH1 | c.46G>T p.D16Y | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM110B | c.48C>A p.S16R | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.199); called by muse, varscan2
- GALNT2 | c.392G>A p.W131* | Nonsense Mutation (SNP) | VAF 15/180 reads (8%) | called by muse, mutect2
- IMPDH2 | c.1331C>T p.S444F | Missense Mutation (SNP) | VAF 58/1072 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- KDM5B | c.3553C>T p.P1185S | Missense Mutation (SNP) | VAF 20/483 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.326); called by muse, mutect2
- MERTK | c.1225C>T p.P409S | Missense Mutation (SNP) | VAF 106/967 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.03); called by muse, mutect2
- MGAT4B | c.658dup p.H220Pfs*5 | Frame Shift Ins (INS) | VAF 5/30 reads (17%) | called by pindel, varscan2
- MUC17 | c.6779C>T p.S2260F | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.713); called by muse, mutect2
- NLRC4 | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 16/229 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- OXSM | c.1345G>A p.G449S | Missense Mutation (SNP) | VAF 26/656 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RELN | c.4492C>A p.L1498M | Missense Mutation (SNP) | VAF 184/835 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); called by mutect2, varscan2
- REN | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 11/231 reads (5%) | SIFT tolerated (0.93); PolyPhen benign (0.095); called by muse, mutect2
- SMG7 | c.1159C>T p.Q387* | Nonsense Mutation (SNP) | VAF 9/179 reads (5%) | called by muse, mutect2
- SPTBN2 | c.6421G>A p.G2141R | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.529); called by muse, mutect2
- TLR7 | c.892C>T p.H298Y | Missense Mutation (SNP) | VAF 41/538 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2
- TMCO4 | c.571C>T p.L191F | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, varscan2
- TRIB1 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 32/290 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- TTC14 | c.321C>A p.F107L | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- TUBB1 | c.1004C>T p.T335I | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- UST | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 308/1080 reads (29%) | SIFT tolerated, low confidence (0.27); PolyPhen probably damaging (0.971); called by muse, varscan2
- VPS13B | c.10636G>A p.D3546N | Missense Mutation (SNP) | VAF 257/1410 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- VWCE | c.2379G>T p.R793S | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by mutect2, varscan2
- WIF1 | c.116G>A p.W39* | Nonsense Mutation (SNP) | VAF 12/25 reads (48%) | called by muse, varscan2
- AGPAT1 | c.105C>T p.F35= | Silent (SNP) | VAF 29/1168 reads (2%) | called by muse, mutect2
- AHNAK | c.11514C>T p.P3838= | Silent (SNP) | VAF 20/692 reads (3%) | called by muse, mutect2
- AHNAK | c.8853C>T p.F2951= | Silent (SNP) | VAF 28/431 reads (6%) | called by muse, mutect2
- AHNAK | c.2265C>T p.P755= | Silent (SNP) | VAF 47/580 reads (8%) | catalogued as rs1329931383; called by muse, mutect2
- ATM | c.3765G>A p.L1255= | Silent (SNP) | VAF 32/434 reads (7%) | called by muse, mutect2
- ATP8B1 | c.252C>T p.F84= | Silent (SNP) | VAF 22/320 reads (7%) | catalogued as COSV52174166; called by muse, mutect2
- CDKL3 | c.1545C>T p.S515= | Silent (SNP) | VAF 33/668 reads (5%) | catalogued as rs773794246; called by muse, mutect2
- CEP72 | c.924C>T p.D308= | Silent (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2, varscan2
- CMTR1 | c.2199C>T p.L733= | Silent (SNP) | VAF 20/269 reads (7%) | called by muse, mutect2
- CSTF2T | c.966T>C p.G322= | Silent (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- CYP2B6 | c.1224C>T p.F408= | Silent (SNP) | VAF 561/4615 reads (12%) | called by muse, mutect2, varscan2
- EGF | c.213G>A p.V71= | Silent (SNP) | VAF 104/847 reads (12%) | catalogued as rs764063043; called by muse, mutect2
- EXPH5 | c.4593G>A p.E1531= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV56200536; called by muse, mutect2, varscan2
- FGF23 | c.489G>A p.E163= | Silent (SNP) | VAF 14/231 reads (6%) | called by muse, mutect2
- FHOD1 | c.1491G>A p.Q497= | Silent (SNP) | VAF 38/62 reads (61%) | called by muse, varscan2
- MPP3 | c.438C>T p.P146= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs1186733093; called by muse, mutect2
- MPRIP | c.1866G>T p.L622= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV57927090; called by muse, mutect2, varscan2
- MYLK4 | c.483G>A p.A161= | Silent (SNP) | VAF 116/903 reads (13%) | catalogued as rs746425107, COSV51138195; called by muse, mutect2
- MYO15A | c.294G>A p.A98= | Silent (SNP) | VAF 15/23 reads (65%) | catalogued as rs1251161014; called by muse, mutect2, varscan2
- NR4A3 | c.1629C>T p.I543= | Silent (SNP) | VAF 30/536 reads (6%) | called by muse, mutect2
- PCDHB16 | c.1011G>T p.V337= | Silent (SNP) | VAF 9/89 reads (10%) | catalogued as COSV53368590; called by muse, mutect2, varscan2
- PLEKHM1 | c.1248G>A p.Q416= | Silent (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2
- PTPRS | c.3366C>T p.L1122= | Silent (SNP) | VAF 16/139 reads (12%) | called by muse, mutect2
- RYR1 | c.11487G>A p.Q3829= | Silent (SNP) | VAF 87/533 reads (16%) | called by muse, varscan2
- SCN9A | c.1875C>T p.N625= | Silent (SNP) | VAF 32/774 reads (4%) | catalogued as rs1168052072, COSV57604510; called by muse, mutect2
- STK32A | c.33G>A p.V11= | Silent (SNP) | VAF 70/429 reads (16%) | called by muse, mutect2
- STS | c.1254A>C p.G418= | Silent (SNP) | VAF 62/768 reads (8%) | called by mutect2, varscan2
- TNIP1 | c.1401G>A p.K467= | Silent (SNP) | VAF 84/302 reads (28%) | called by muse, mutect2, varscan2
- ZDHHC5 | c.693C>T p.P231= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as rs770503441; called by mutect2, varscan2
- ZNF169 | c.897C>T p.F299= | Silent (SNP) | VAF 31/95 reads (33%) | called by muse, mutect2, varscan2
- ZNF33A | c.1050C>T p.H350= (on ENST00000458705 / NM_006974.3; = p.H351= on NM_006954.2) | Silent (SNP) | VAF 18/556 reads (3%) | called by muse, mutect2
- DCHS2 | n.8360C>T | RNA (SNP) | VAF 179/467 reads (38%) | called by muse, mutect2, varscan2
- TRPV2 | chr17:16439351 T>G | 3'Flank (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- TTN | c.10360+2730T>C | Intron (SNP) | VAF 30/532 reads (6%) | catalogued as COSV60256561; called by muse, mutect2
